National Lung Screening Trial (NLST) participant 205046 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 68 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 90 effective mAs, display field of view 36 cm, reconstruction filter Phillips D / Phillips C.
- T1 (day 363): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 35 effective mAs, display field of view 35 cm, reconstruction filter Siemens B30.
- T2 (day 731): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 50 effective mAs, display field of view 37 cm, reconstruction filter Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (8 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Emphysema.
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 30 mm, longest perpendicular diameter 20 mm; margins smooth; predominant attenuation other; greatest diameter on CT slice 27; new (not pre-existing on earlier images).
- T1 abnormality 2: Emphysema.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 13 mm, longest perpendicular diameter 10 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 49; new (not pre-existing on earlier images).
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 10 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 23; new (not pre-existing on earlier images).
- T2 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 7 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 105.
- T2 abnormality 4: Emphysema.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T2; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 777, study year T2. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Primary tumour location: right upper lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: well differentiated (G1). Tumour size on pathology: 15 mm. AJCC 6th edition staging: stage IB (best stage, from pathologic TNM); clinical T1 NX MX; pathologic T2 N0 M0 (stage IB). AJCC 7th edition staging: stage IB; clinical T1a N0 M0; pathologic T2a N0 M0. Summary stage: regional.

Follow-up
Last known free of lung cancer: day 777 (for ACRIN participants with lung cancer this field holds the diagnosis date).
